Somatic mutation profile of tumor specimen TCGA-EL-A3T3-01A (aliquot TCGA-EL-A3T3-01A-11D-A22D-08) from TCGA case TCGA-EL-A3T3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 63.1 years (23,043 days).
Specimen TCGA-EL-A3T3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78436cf9-f436-4dc1-89d2-043f5879d363.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3T3-11A (Solid Tissue Normal), aliquot TCGA-EL-A3T3-11A-11D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0052e379-29be-4d2f-8694-25bb38c6cdc5

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AFDN | c.4339C>G p.Q1447E | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.115); catalogued as COSV60043708, COSV60056148; called by muse, mutect2
- BPTF | c.1756G>C p.D586H | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV58836430; called by muse, mutect2
- C10orf90 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.173); catalogued as COSV52954203; called by muse, mutect2
- EGFLAM | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV59300748; called by muse, mutect2
- GPR78 | c.783-2A>T p.X261_splice | Splice Site (SNP) | VAF 51/127 reads (40%) | catalogued as COSV66762991; called by muse, mutect2, varscan2
- LIPT1 | c.416C>G p.A139G | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV60739633; called by muse, mutect2
- RASGRP1 | c.485A>C p.E162A | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV60364925; called by muse, mutect2, varscan2
- RBBP4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV65132517; called by muse, mutect2
- TMEM225 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776556129, COSV66693147; called by muse, mutect2, varscan2
- TMEM255B | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64703866; called by muse, mutect2, varscan2
- FLNA | c.33C>T p.S11= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs1557180269, COSV61042204; called by muse, mutect2, varscan2
- GPAM | c.1650C>T p.S550= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as rs761149340, COSV62080983; called by muse, mutect2, varscan2
- TRIM51 | c.1308T>C p.N436= | Silent (SNP) | VAF 12/264 reads (5%) | catalogued as rs766481645, COSV55266126; called by muse, mutect2
